Somatic mutation profile of tumor specimen TCGA-HD-7832-01A (aliquot TCGA-HD-7832-01A-11D-2129-08) from TCGA case TCGA-HD-7832, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.5 years (19,192 days).
Specimen TCGA-HD-7832-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d4d182b-9af0-46a5-985f-42f3a04e3a79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-7832-10A (Blood Derived Normal), aliquot TCGA-HD-7832-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fa2d5d1-7123-45f9-b541-35d41e1dde30

The open-access MAF lists 111 somatic variants for this specimen: 76 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 33, Nonsense Mutation 3, 5'UTR 2, Frame Shift Del 2, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.4074G>C p.Q1358H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV99797763; called by muse, mutect2, varscan2
- ALKAL1 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV100660069; called by muse, mutect2, varscan2
- ANLN | c.1540A>C p.M514L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as COSV99731748; called by muse, varscan2
- ARHGEF15 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.31); catalogued as COSV100729968; called by muse, mutect2, varscan2
- ASAP1 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 194/333 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV63053670; called by muse, mutect2, varscan2
- ASXL1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs545224250, COSV60102645, COSV60104059; called by muse, mutect2
- ATRN | c.3124C>T p.L1042F | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs201051647, COSV53524333; called by muse, mutect2, varscan2
- CAPNS1 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99874413; called by muse, mutect2, varscan2
- CD180 | c.1621A>G p.S541G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99842056; called by muse, mutect2, varscan2
- CDK13 | c.3970C>T p.Q1324* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV99474956; called by muse, mutect2, varscan2
- CHD7 | c.6425C>T p.S2142F | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV71107554; called by muse, mutect2, varscan2
- CNTN5 | c.2239C>T p.R747* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs780931539, COSV54291267; called by muse, mutect2, varscan2
- CNTROB | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.717); catalogued as COSV100972587; called by muse, mutect2, varscan2
- DHRS2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99158696; called by muse, mutect2, varscan2
- DNAH7 | c.7544G>A p.R2515Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs546179605, COSV56761070; called by muse, mutect2, varscan2
- EGFR | c.2900A>C p.E967A | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99286255; called by muse, mutect2, varscan2
- ELAVL4 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100836502; called by muse, mutect2, varscan2
- ENTPD5 | c.788C>G p.T263S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.035); catalogued as COSV100592134; called by muse, mutect2, varscan2
- ERBB3 | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57249311; called by muse, mutect2, varscan2
- FABP9 | c.13T>C p.F5L | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.155); catalogued as COSV100986913; called by muse, mutect2, varscan2
- FBLN1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53051085; called by muse, mutect2, varscan2
- FBN2 | c.8521G>A p.D2841N | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs779172018, COSV99324442; called by muse, mutect2, varscan2
- FBXO46 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV100479911; called by muse, mutect2, varscan2
- GMPS | c.1766G>T p.R589L | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55807722, COSV55807905, COSV99902842; called by muse, mutect2, varscan2
- GPR158 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV100892719; called by muse, mutect2, varscan2
- GRAMD1B | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1233169320, COSV59203826; called by muse, mutect2, varscan2
- GRIK3 | c.2290G>A p.G764S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100901145; called by muse, mutect2, varscan2
- HUWE1 | c.11216G>A p.R3739Q | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.885); catalogued as rs782183494, COSV53336036, COSV99474143; called by muse, mutect2, varscan2
- IGF2 | c.439G>A p.E147K (on ENST00000434045 / NM_001127598.3; = p.E91K on NM_000612.6) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV56101232; called by muse, mutect2, varscan2
- IL1R1 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs771704915, COSV99292312; called by muse, mutect2, varscan2
- INPP5F | c.1154_1156del p.K385del | In Frame Del (DEL) | VAF 32/114 reads (28%) | catalogued as rs780065034; called by pindel, varscan2
- INTU | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs745930797, COSV99611382; called by muse, mutect2, varscan2
- IZUMO4 | c.253T>G p.Y85D | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100642364; called by muse, mutect2, varscan2
- KATNIP | c.3236A>G p.N1079S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560393620, COSV55193461; called by muse, mutect2, varscan2
- KCTD3 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs751541355, COSV99378742; called by muse, mutect2, varscan2
- KMT2E | c.4858C>G p.Q1620E | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99995685; called by muse, mutect2, varscan2
- KPRP | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100908653; called by muse, mutect2, varscan2
- LRRK2 | c.7325G>A p.R2442H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs749224394, COSV100108924; called by muse, mutect2, varscan2
- MOCOS | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.607); catalogued as rs141623345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKAIN1 | c.505A>C p.K169Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.856); catalogued as COSV99744362; called by muse, mutect2, varscan2
- NOTCH3 | c.548G>C p.C183S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM052272, COSV54635610; called by muse, mutect2, varscan2
- OLAH | c.430G>T p.D144Y (on ENST00000378228 / NM_001039702.3; = p.D197Y on NM_018324.3) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100984600; called by muse, mutect2, varscan2
- PCDHGC3 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.545); catalogued as rs772195653, COSV52773618, COSV99337515; called by muse, mutect2, varscan2
- PEX11G | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99675785; called by muse, mutect2, varscan2
- PHRF1 | c.4732A>T p.I1578F (on ENST00000264555 / NM_001286581.2; = p.I1577F on NM_020901.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99199381; called by muse, mutect2, varscan2
- PIK3R6 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs556552630, COSV61004502; called by muse, mutect2, varscan2
- PLA1A | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99845655; called by muse, mutect2, varscan2
- PPFIA2 | c.1916C>G p.S639C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100331411; called by muse, mutect2, varscan2
- PTK2 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.133); catalogued as COSV100569276; called by muse, mutect2, varscan2
- RAB4B | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs759614557, COSV100826407; called by muse, mutect2, varscan2
- RYR3 | c.3208A>G p.K1070E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV66810090; called by muse, mutect2, varscan2
- SDK1 | c.4694G>A p.S1565N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101268694; called by muse, mutect2, varscan2
- SEL1L2 | c.1826A>C p.H609P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99532462; called by muse, mutect2, varscan2
- SEMA5B | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV99530618; called by muse, mutect2, varscan2
- SFRP4 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.616); catalogued as rs748182253, COSV71412330; called by muse, mutect2, varscan2
- SPATA6 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100893008; called by muse, mutect2, varscan2
- SSTR4 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.51); catalogued as COSV99658291; called by muse, mutect2, varscan2
- STK32C | c.1162A>T p.M388L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as COSV100061709; called by muse, mutect2, varscan2
- SYCP2 | c.3865T>A p.Y1289N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV100697917; called by muse, mutect2, varscan2
- TCEA2 | c.783C>A p.C261* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100180578; called by muse, mutect2, varscan2
- TGOLN2 | c.418T>C p.S140P | Missense Mutation (SNP) | VAF 215/593 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as COSV99964921; called by muse, mutect2, varscan2
- TMEM245 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.347); catalogued as COSV101002163; called by muse, mutect2
- TSGA10IP | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs533013932, COSV101598378; called by mutect2, varscan2
- TTN | c.2068C>G p.H690D (on ENST00000591111; = p.H644D on NM_003319.4) | Missense Mutation (SNP) | VAF 45/134 reads (34%) | PolyPhen benign (0.025); catalogued as COSV100591823, COSV60132803; called by muse, mutect2, varscan2
- UBXN10 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100907721; called by muse, mutect2, varscan2
- UNC13C | c.3105G>A p.M1035I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV99510723; called by muse, mutect2, varscan2
- UROS | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as rs1322143987, COSV100908853; called by muse, mutect2, varscan2
- WDR27 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); catalogued as rs778546983, COSV100357999; called by muse, mutect2, varscan2
- WDR33 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100459481; called by muse, mutect2, varscan2
- WSCD2 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as rs779899520, COSV99773966; called by muse, mutect2
- ZNF302 | c.507+2G>A | Missense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs1248507959, COSV101416426; called by muse, mutect2, varscan2
- ZNF665 | c.1042C>G p.Q348E (on ENST00000600412; = p.Q413E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.917); catalogued as COSV101127887; called by muse, mutect2, varscan2
- DSG1 | c.1548del p.D516Efs*46 | Frame Shift Del (DEL) | VAF 41/156 reads (26%) | called by mutect2, pindel, varscan2
- EVI5 | c.107_109dup p.N36dup | In Frame Ins (INS) | VAF 50/163 reads (31%) | called by mutect2, pindel, varscan2
- SUPV3L1 | c.34del p.L12Sfs*56 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.1831C>T p.L611= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV50782044; called by muse, mutect2, varscan2
- ASB1 | c.117G>A p.T39= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs759887551, COSV99223091; called by muse, mutect2, varscan2
- ATG16L1 | c.1290G>A p.R430= (on ENST00000392017 / NM_030803.7; = p.R411= on NM_017974.4) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs752655408, COSV100731244; called by muse, mutect2, varscan2
- AVPR1A | c.72C>T p.G24= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100146756; called by muse, mutect2, varscan2
- AXDND1 | c.813A>G p.R271= | Silent (SNP) | VAF 61/87 reads (70%) | catalogued as COSV100858237; called by muse, mutect2, varscan2
- CACNA1I | c.3867G>A p.A1289= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100359022; called by muse, mutect2, varscan2
- CLCN6 | c.1335G>A p.P445= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1302255634, COSV100411509, COSV56738355; called by muse, mutect2, varscan2
- CSPG4 | c.4905G>A p.Q1635= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs145039359; called by muse, mutect2, varscan2
- CTAGE1 | c.1956A>G p.E652= | Silent (SNP) | VAF 74/256 reads (29%) | catalogued as COSV101194415; called by muse, mutect2, varscan2
- ERICH3 | c.2709G>T p.V903= | Silent (SNP) | VAF 88/276 reads (32%) | catalogued as COSV100443215; called by muse, mutect2, varscan2
- HOXC9 | c.636C>T p.L212= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs764826136, COSV100327359; called by muse, mutect2, varscan2
- KIF1B | c.1797C>T p.P599= (on ENST00000377086 / NM_001365952.1; = p.P553= on NM_015074.3) | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs1188607388, COSV99822307; called by muse, mutect2, varscan2
- LARGE1 | c.2085C>T p.F695= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV100504427; called by muse, mutect2, varscan2
- MAGEB4 | c.339G>A p.T113= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs982033983, COSV64396815; called by muse, mutect2, varscan2
- MCF2L | c.1497C>T p.I499= (on ENST00000375608; = p.I467= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs770872135, COSV100982068; called by muse, mutect2, varscan2
- MUC7 | c.264C>T p.H88= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs1456422122, COSV100512167; called by muse, mutect2, varscan2
- MYH10 | c.3078C>T p.A1026= | Silent (SNP) | VAF 72/205 reads (35%) | catalogued as COSV99343920; called by muse, mutect2, varscan2
- OR1C1 | c.543C>T p.L181= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV101376176; called by muse, mutect2, varscan2
- OR8K3 | c.204C>T p.F68= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV57131567; called by muse, mutect2, varscan2
- OTOP2 | c.528A>T p.T176= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV100140291; called by muse, mutect2, varscan2
- PCDHB9 | c.1791C>T p.G597= | Silent (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.1269A>T p.G423= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101378650; called by muse, mutect2
- PPARGC1B | c.2412C>T p.F804= | Silent (SNP) | VAF 128/153 reads (84%) | catalogued as rs1158480787, COSV100494426; called by muse, mutect2, varscan2
- SLC2A13 | c.1672C>T p.L558= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV99785770; called by muse, mutect2, varscan2
- SLITRK5 | c.2076G>A p.R692= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100280166; called by muse, mutect2, varscan2
- SNX14 | c.660A>G p.Q220= (on ENST00000314673 / NM_001350535.1; = p.Q176= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100121392; called by muse, mutect2, varscan2
- SOX11 | c.168C>T p.F56= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100430695; called by muse, mutect2, varscan2
- TBC1D9 | c.3669G>A p.E1223= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101464247, COSV71307367; called by muse, mutect2, varscan2
- TMEM59L | c.1009C>T p.L337= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99449917; called by muse, mutect2, varscan2
- TRPV5 | c.2004C>A p.P668= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99520037; called by muse, mutect2, varscan2
- TTN | c.20706T>A p.S6902= (on ENST00000591111; = p.S5975= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100591822; called by muse, mutect2, varscan2
- ZNF70 | c.996C>T p.G332= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs752943786, COSV59532005; called by muse, mutect2, varscan2
- ZNF761 | c.2112C>T p.S704= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV61889478; called by muse, mutect2, varscan2
- HNRNPA1 | c.-2T>A | 5'UTR (SNP) | VAF 33/96 reads (34%) | catalogued as COSV99267328; called by muse, mutect2, varscan2
- SWI5 | c.-41C>T | 5'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as rs1564371479, COSV100199532; called by muse, mutect2, varscan2
